Somatic mutation profile of tumor specimen MMRF_1608_1_BM_CD138pos (aliquot MMRF_1608_1_BM_CD138pos_T2_KBS5U_K11919) from MMRF case MMRF_1608, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,392 days).
Specimen MMRF_1608_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9d4b819-ca7e-4a40-975e-86779aaea4ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1608_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1608_1_PB_Whole_C7_KBS5U_K11900; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/023c963b-9aa7-46b7-824f-c1fc32e071b4

The open-access MAF lists 104 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 26, Intron 14, Silent 13, 5'UTR 5, 3'Flank 5, 5'Flank 3, Nonsense Mutation 2, RNA 2, Nonstop Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs374574602; called by muse, mutect2, varscan2
- AGMO | c.910T>C p.W304R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs950355924; called by muse, mutect2, varscan2
- CTTNBP2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775961843, COSV50392601, COSV99353371; called by muse, mutect2, varscan2
- FOXO3 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59629218; called by muse, mutect2, varscan2
- GABRB2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 195/285 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs140795978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCC1 | c.962A>G p.Q321R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs768718516; called by muse, mutect2, varscan2
- IGHV2-70 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as rs370713802; called by muse, varscan2
- IGKJ4 | c.35A>C p.K12T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | PolyPhen benign (0.069); catalogued as rs369448920; called by muse, mutect2, varscan2
- IGLV3-1 | c.145A>C p.K49Q | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs192957059; called by muse, varscan2
- IGLV3-1 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.331); catalogued as rs61731690; called by muse, varscan2
- KRT31 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs141715467; called by muse, mutect2, varscan2
- KRT80 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs753236407; called by mutect2, varscan2
- PCSK2 | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs757047936; called by muse, mutect2, varscan2
- RASA2 | c.135T>A p.C45* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV99656146; called by muse, mutect2, varscan2
- RTEL1 | c.3651G>C p.W1217C | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV53929713; called by muse, mutect2, varscan2
- THOC6 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1233187682, COSV99560515; called by muse, mutect2, varscan2
- TTF2 | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774489774; called by muse, mutect2, varscan2
- ANKRD42 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BZW1 | c.72A>T p.K24N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CENPS | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCLK1 | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DLX2 | c.902_915del p.H301Pfs*97 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, varscan2
- IGHV2-70D | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, varscan2
- IGHV2-70D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- IGHV2-70D | c.96A>T p.K32N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IGHV2-70D | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, varscan2
- MORC1 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MST1R | c.3850G>T p.G1284C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5AC | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- PCDH12 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 259/363 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPGEF2 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- RASA2 | c.1827-2A>T p.X609_splice | Splice Site (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2
- RASSF6 | c.242C>A p.T81N (on ENST00000342081 / NM_201431.2; = p.T49N on NM_177532.5) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.189); called by muse, varscan2
- RBM15 | c.2933A>G p.*978Wext*3 | Nonstop Mutation (SNP) | VAF 133/299 reads (44%) | called by muse, mutect2, varscan2
- SLC16A7 | c.627T>A p.N209K | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABHD16A | c.1581G>A p.L527= | Silent (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- CTSW | c.939A>G p.S313= | Silent (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- H2BC21 | c.369C>T p.T123= | Silent (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- IFIT1B | c.861G>A p.L287= | Silent (SNP) | VAF 85/196 reads (43%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.54A>G p.L18= | Silent (SNP) | VAF 30/72 reads (42%) | called by muse, varscan2
- LGR5 | c.2098C>T p.L700= | Silent (SNP) | VAF 48/115 reads (42%) | called by muse, mutect2, varscan2
- LRIG3 | c.3090G>A p.S1030= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as rs557973342; called by muse, mutect2, varscan2
- MINDY3 | c.597C>T p.N199= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs371111421; called by muse, mutect2, varscan2
- NAB1 | c.639T>C p.S213= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- PLXND1 | c.4443C>T p.L1481= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, varscan2
- PNLIPRP2 | c.519C>T p.G173= | Silent (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- SLC35F3 | c.693C>T p.S231= (on ENST00000366617 / NM_001300845.1; = p.S300= on NM_173508.4) | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs1456976267, COSV64018491; called by muse, mutect2, varscan2
- ZFP37 | c.1869T>C p.H623= | Silent (SNP) | VAF 9/230 reads (4%) | called by muse, mutect2
- AC017104.4 | chr2:231509049 A>C | 5'Flank (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- AC090114.3 | n.749G>A | RNA (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- ACCS | c.654+94T>C | Intron (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2
- ACCS | c.833+124T>C | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- AOC4P | chr17:42867165 C>T | 5'Flank (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- BCAS1 | chr20:53940285 T>G | 3'Flank (SNP) | VAF 39/71 reads (55%) | called by muse, varscan2
- BTBD3 | c.*1523A>C | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- C4orf50 | c.-940C>T | 5'UTR (SNP) | VAF 39/78 reads (50%) | catalogued as rs1311298609; called by muse, mutect2, varscan2
- CD160 | c.539-35G>T | Intron (SNP) | VAF 106/340 reads (31%) | called by muse, mutect2, varscan2
- CFAP61 | c.2503+2526T>A | Intron (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- CHRNA3 | c.83-162C>A | Intron (SNP) | VAF 18/81 reads (22%) | catalogued as rs986081699; called by muse, mutect2, varscan2
- CNTN4 | c.*1560T>C | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- COL10A1 | c.*2T>C | 3'UTR (SNP) | VAF 60/211 reads (28%) | catalogued as rs1264721626; called by mutect2, varscan2
- CSMD1 | chr8:2937896 T>G | 3'Flank (SNP) | VAF 31/73 reads (42%) | catalogued as rs1048769866; called by muse, mutect2, varscan2
- CYP2U1 | c.*513C>T | 3'UTR (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- DNAJB7 | c.*470C>G | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- DTX1 | c.-356A>G | 5'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- EGLN2 | c.*79C>T | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2
- FAM166A | c.748-86C>A | Intron (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- FERMT3 | c.-11C>T | 5'UTR (SNP) | VAF 97/185 reads (52%) | called by muse, mutect2, varscan2
- FIBIN | c.*636G>T | 3'UTR (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- GPM6B | c.-441G>A | 5'UTR (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- GPR157 | c.*926A>G | 3'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- HES1 | c.*486T>C | 3'UTR (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- IGLL5 | c.-98T>C | 5'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- INSIG1 | c.*724C>T | 3'UTR (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- INTS6 | c.*275G>A | 3'UTR (SNP) | VAF 32/97 reads (33%) | catalogued as rs1039756786; called by muse, varscan2
- ITIH5 | c.*3284C>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | catalogued as rs1409251028; called by muse, mutect2
- KCNC1 | chr11:17781878 C>A | 3'Flank (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- LIMD1 | c.*6712G>A | 3'UTR (SNP) | VAF 55/113 reads (49%) | catalogued as rs1050577314; called by muse, mutect2, varscan2
- LINC02253 | n.575-1206C>T | Intron (SNP) | VAF 14/372 reads (4%) | catalogued as rs1038371878; called by muse, mutect2
- LNPK | c.*2564_*2571del | 3'UTR (DEL) | VAF 45/86 reads (52%) | called by mutect2, pindel, varscan2
- LTB | c.163-157T>A | Intron (SNP) | VAF 144/223 reads (65%) | catalogued as rs186288832; called by muse, mutect2, varscan2
- LTB | c.162+15C>T | Intron (SNP) | VAF 84/129 reads (65%) | catalogued as rs541177858; called by muse, mutect2, varscan2
- MALRD1 | c.*38T>A | 3'UTR (SNP) | VAF 101/189 reads (53%) | called by muse, mutect2, varscan2
- MARCHF9 | c.*914G>C | 3'UTR (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- MIR5195 | n.4C>T | RNA (SNP) | VAF 56/116 reads (48%) | called by muse, mutect2, varscan2
- NTRK3 | c.*12924T>C | 3'UTR (SNP) | VAF 20/80 reads (25%) | called by muse, varscan2
- OR52E4 | chr11:5885423 T>C | 3'Flank (SNP) | VAF 26/88 reads (30%) | called by mutect2, varscan2
- PALM2AKAP2 | chr9:110171971 C>T | 3'Flank (SNP) | VAF 46/183 reads (25%) | called by muse, mutect2, varscan2
- PAX5 | c.*6576A>G | 3'UTR (SNP) | VAF 45/160 reads (28%) | called by muse, mutect2, varscan2
- PGAP4 | c.*1403T>G | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- PRPF40A | c.276+106T>G | Intron (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- PTHLH | c.101+108C>T | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- RAB30 | c.*8314T>G | 3'UTR (SNP) | VAF 31/48 reads (65%) | called by muse, varscan2
- RAB30 | c.*8249T>C | 3'UTR (SNP) | VAF 43/57 reads (75%) | called by muse, varscan2
- SMC3 | c.*88G>A | 3'UTR (SNP) | VAF 63/156 reads (40%) | called by muse, mutect2, varscan2
- SPECC1 | c.2351+6735G>A | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- SPRED1 | c.*5425_*5438del | 3'UTR (DEL) | VAF 43/93 reads (46%) | called by mutect2, pindel, varscan2
- TBP | c.*89T>C | 3'UTR (SNP) | VAF 87/278 reads (31%) | called by muse, mutect2, varscan2
- TFDP3 | c.*167G>A | 3'UTR (SNP) | VAF 126/144 reads (88%) | catalogued as rs190448749, COSV59538143; called by muse, mutect2, varscan2
- THTPA | chr14:23556156 ins G | 5'Flank (INS) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- TTN | c.10303+1283C>T | Intron (SNP) | VAF 63/139 reads (45%) | catalogued as rs773449874, COSV60358807; called by muse, mutect2, varscan2
- ZC3H6 | c.*5696A>G | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- ZNF582 | c.-81+32G>A | Intron (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
